Somatic mutation profile of tumor specimen TCGA-DJ-A3VF-01A (aliquot TCGA-DJ-A3VF-01A-11D-A23M-08) from TCGA case TCGA-DJ-A3VF, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 60.9 years (22,234 days).
Specimen TCGA-DJ-A3VF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d00c8f2d-9238-41ca-90d3-b23c5eb8b5e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A3VF-10A (Blood Derived Normal), aliquot TCGA-DJ-A3VF-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ec8c071-38e1-49b1-a356-6ebf6ebc72df

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 4, Silent 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BBS12 | c.1886C>G p.S629C | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.232); catalogued as COSV58561500; called by muse, mutect2, varscan2
- CRYM | c.815T>A p.L272Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54830079; called by muse, mutect2, varscan2
- FLOT2 | c.700-1G>T p.X234_splice | Splice Site (SNP) | VAF 7/60 reads (12%) | catalogued as COSV67528861; called by muse, mutect2, varscan2
- IMPG1 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs147225489; called by muse, mutect2, varscan2
- CKAP4 | c.906C>T p.S302= | Silent (SNP) | VAF 24/164 reads (15%) | catalogued as COSV65172184; called by muse, mutect2, varscan2
- DGCR2 | c.1179C>T p.G393= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV54216755; called by muse, mutect2, varscan2
- SLC8A3 | c.369A>T p.T123= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV63519468; called by muse, mutect2, varscan2
